Surgical pathology report (de-identified scan), TCGA case TCGA-29-2432, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2432-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-2432

Surg Path

CLINICAL HISTORY:

Ascites, increased CA 125, pelvic mass (9 cm, complex).

GROSS EXAMINATION:

A. "Omentum (AF1)", received fresh for frozen section consultation is a 7.5 x 6.5 x 1.5 cm aggregate of tan, firm, rubbery tumor and associated fibroadipose tissue. A representative section of mass is frozen as AF1. The frozen section remnant is submitted in block A1. Additional representative sections are submitted in blocks A2-3.

B. "Right tube and ovary", received fresh and placed in formalin is a 23 gram adnexal specimen remarkable for a 4.5 x 4.3 x 2.9 cm ovary blanketed with pink-tan, friable tumor involves the ovarian cortex. The remaining ovary demonstrates multiple corpora albicantia (0.4 cm in greatest dimension), a hemorrhagic corpus luteum 0.8 cm in greatest dimension), as well as a serous fluid-filled cyst (0.5 cm in greatest dimension). The fallopian tube (5.5 cm long x 0.5 cm diameter) has serosal surface deposits of the aforementioned ovarian tumor and an unremarkable pinpoint lumen.

BLOCK SUMMARY:

B1-2- representative ovary with tumor

B3- fallopian tube

C. "Omentum #2", received fresh and placed in formalin is a 6.5 x 6 x 2 cm aggregate of pink-tan tissue that consists of firm, rubbery, tan tumor and associated fibroadipose tissue. Representative sections of the tumor are submitted in blocks C1-2.

D. "Left tube and ovary", received fresh and placed in formalin is a 29 gram adnexal specimen remarkable for a 4.5 x 3.2 x 2.5 cm ovary blanketed with friable, pink-tan tumor that grossly involves underlying ovarian cortex. The uninvolved ovary has a 1.2 x 1 x 0.8 cm firm, yellow, fibrous mass at the lateral pole. The attached fallopian tube (5.6 cm long x 0.5 cm diameter) has a serosal surface involved by the aforementioned friable tumor and an unremarkable pinpoint lumen.

BLOCK SUMMARY:

D1- tumor with invasion into ovary

D2- firm, yellow, ovarian nodule and fallopian tube

D3- additional ovary and fallopian tube

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- poorly differentiated adenocarcinoma, compatible with an ovarian primary

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Bilateral salpingo-oophorectomy and omentectomy

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is

[page 2 of 2]
transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM" (OMENTECTOMY): [REDACTED]

METASTATIC SEROUS ADENOCARCINOMA, 7.5 CM.

B. "OVARY AND FALLOPIAN TUBE, RIGHT" (SALPINGO-OOPHORECTOMY):

"RIGHT OVARY":

TYPE: SEROUS ADENOCARCINOMA
FIGO GRADE: 3
TUMOR SIZE: 4.5 X 4.3 X 2.9 CM.
WEIGHT: 23 GRAMS
SEROSA: INVOLVED.

FALLOPIAN TUBE: METASTATIC SEROUS ADENOCARCINOMA.

C. "OMENTUM, #2" (OMENTECTOMY):

METASTATIC SEROUS ADENOCARCINOMA, 6.5 CM.

D. "OVARY AND FALLOPIAN TUBE, LEFT" (SALPINGO-OOPHORECTOMY):

"LEFT OVARY":

TYPE: SEROUS ADENOCARCINOMA
FIGO GRADE: 3
TUMOR SIZE: 4.5 X 3.2 X 2.5 CM.
WEIGHT: 29 GRAMS
SEROSA: INVOLVED
ADDITIONAL FINDINGS: BENIGN FIBROMA, 1.2 CM.

FALLOPIAN TUBE: METASTATIC SEROUS ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file a619e847-6144-447e-b8b3-995db4c62286 (TCGA-29-2432.9DE0CA7F-0603-46A9-9C69-7E2196CBFB6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).